CCDI case PBCMGT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/1b8e19d4-6f9c-4e56-9a6c-52cb6af54062

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8010/6; Tissue or organ of origin: Endometrium; Age at diagnosis: 15.8 years (5,786 days).

Biospecimens (3 samples)
- Sample 0DV5RU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV5S6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DV5SF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
